Gene-level copy-number profile of tumor specimen C3N-01028-02 from CPTAC case C3N-01028, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 72.9 years (26,623 days).
Specimen C3N-01028-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d7653528-3e1b-493d-9068-534cab586d7c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01028-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/19772a94-637f-4997-b4f8-73eb67c971b0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 69; copy number 1: 16,989; copy number 2: 36,286; copy number 3: 3,701; copy number 4: 1,689; copy number 5: 5; copy number 6: 16; copy number 7: 86; copy number 9: 42; copy number 11: 32.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–1): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:767,382–768,930, 1 gene: BRD9P2.
- chr9:21,453,802–21,559,900, 1 gene (within-gene range 0–1): MIR31HG.
- chr9:21,480,839–23,438,700, 26 genes (within-gene range 0–1): IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr13:21,126,271–21,149,084, 3 genes: AL161613.1, SNORD27, SAP18.
- chr14:105,583,731–105,601,728, 2 genes: IGHA2, IGHE.
- chr14:105,621,116–105,644,790, 2 genes (within-gene range 0–1): MIR8071-1, IGHG2.
- chr14:105,647,924–105,649,057, 1 gene: COPDA1.
- chr16:32,475,051–32,478,250, 1 gene: ABCD1P3.
- chr17:8,474,207–8,630,761, 4 genes (within-gene range 0–1): MYH10, RNU7-43P, PPIAP52, AC025518.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 181 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:110,682,286–115,147,288, 87 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr5:40,240,167–41,261,438, 15 genes, copy number 7: LINC00604, RNU1-150P, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1, MROH2B, C6.
- chr9:6,195,934–6,645,729, 10 genes, copy number 9 (within-gene range 4–9): GTF3AP1, IL33, AL360221.1, SELENOTP1, TPD52L3, UHRF2, AL133480.1, GLDC, RN7SL25P, AL353718.1.
- chr9:35,088,688–36,677,683, 64 genes, copy number 9–11 (broad region; genes not listed).
- chr14:37,197,913–37,596,059, 5 genes, copy number 5 (within-gene range 4–5): MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1.

Autosomal genes at a single copy (total copy number 1): 14,588. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
